Somatic mutation profile of tumor specimen C3L-08241-01 (aliquot CPT0485320006) from CPTAC case C3L-08241, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 68.3 years (24,946 days).
Specimen C3L-08241-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 782bc4da-5a26-4381-9834-0f5a26827d72.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08241-31 (Blood Derived Normal), aliquot CPT0485470003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3b64df7-bceb-4504-a908-6447a0ba0b4f

The open-access MAF lists 571 somatic variants for this specimen: 423 protein-altering or splice-affecting, 133 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 320, Silent 133, Frame Shift Del 60, Nonsense Mutation 17, Frame Shift Ins 16, Intron 7, 3'UTR 3, Splice Region 3, In Frame Del 3, Splice Site 2, 5'UTR 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GATA2 | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 21/320 reads (7%) | catalogued as rs387906632, CM117933, COSV62007611; ClinVar: pathogenic; called by muse, mutect2
- RHOA | c.125A>G p.Y42C | Missense Mutation (SNP) | VAF 242/324 reads (75%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs1057519954, COSV69041523, COSV69041892, COSV69042190; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.692dup p.S232Qfs*3 | Frame Shift Ins (INS) | VAF 91/189 reads (48%) | catalogued as rs377767334, COSV61691229; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TENT5D | c.205A>C p.S69R | Missense Mutation (SNP) | VAF 116/306 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57634984, COSV57635195, COSV57638952; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 132/217 reads (61%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.2360C>T p.A787V | Missense Mutation (SNP) | VAF 83/272 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV101329924; called by muse, mutect2, varscan2
- ABCC9 | c.3805T>G p.L1269V | Missense Mutation (SNP) | VAF 97/263 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.186); catalogued as COSV53978035, COSV99687670; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 43/249 reads (17%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADPRHL1 | c.1963G>A p.V655M | Missense Mutation (SNP) | VAF 189/656 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.045); catalogued as rs564314253; called by muse, mutect2, varscan2
- AGPAT5 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 91/258 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.388); catalogued as rs779056908, COSV53446975; called by muse, mutect2, varscan2
- AHCTF1 | c.730C>T p.R244C (on ENST00000366508; = p.R218C on NM_015446.5) | Missense Mutation (SNP) | VAF 23/305 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753602111, COSV58254928; called by muse, mutect2
- AMER2 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 172/657 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV63438534; called by muse, mutect2, varscan2
- AMOTL2 | c.1354C>T p.R452W | Missense Mutation (SNP) | VAF 35/620 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs761943709; called by muse, mutect2
- ANXA11 | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 11/274 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99626903; called by muse, mutect2
- AP4B1 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 135/443 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs377418341; called by muse, mutect2, varscan2
- ARHGEF28 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 167/687 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.72); catalogued as rs370473647; called by muse, mutect2, varscan2
- ARID1A | c.5942G>A p.C1981Y | Missense Mutation (SNP) | VAF 126/380 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61373894; called by muse, mutect2, varscan2
- ATP5F1B | c.125C>A p.P42H | Missense Mutation (SNP) | VAF 111/322 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.135); catalogued as COSV56261737; called by muse, mutect2, varscan2
- ATXN7L3 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 98/287 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV66989651; called by muse, varscan2
- BCLAF1 | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 68/320 reads (21%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.888); catalogued as rs144796865; called by muse, mutect2, varscan2
- BDP1 | c.6976G>A p.E2326K | Missense Mutation (SNP) | VAF 282/350 reads (81%) | SIFT tolerated (0.15); PolyPhen benign (0.066); catalogued as rs780747194, COSV100703662, COSV62430642; called by mutect2, varscan2
- BNC2 | c.2407G>A p.A803T | Missense Mutation (SNP) | VAF 136/394 reads (35%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.978); catalogued as rs748296825, COSV101034609; called by muse, mutect2, varscan2
- C11orf95 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 110/498 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58311326; called by muse, mutect2, varscan2
- C4orf54 | c.4640del p.P1547Qfs*70 | Frame Shift Del (DEL) | VAF 94/297 reads (32%) | catalogued as rs763082793; called by mutect2, pindel, varscan2
- C4orf54 | c.3820G>A p.E1274K | Missense Mutation (SNP) | VAF 73/235 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1386888150; called by muse, mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 86/321 reads (27%) | catalogued as rs762770988, COSV62756627; called by pindel, varscan2
- CBLL2 | c.1195T>C p.C399R | Missense Mutation (SNP) | VAF 185/518 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs780625523; called by muse, mutect2, varscan2
- CCDC148 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 147/198 reads (74%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1162579240; called by muse, mutect2, varscan2
- CCDC185 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 235/636 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.32); catalogued as rs779253449; called by muse, mutect2, varscan2
- CCHCR1 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 204/826 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.673); catalogued as rs776296708; called by muse, mutect2, varscan2
- CDH13 | c.106T>G p.F36V | Missense Mutation (SNP) | VAF 119/351 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs767665074; called by muse, mutect2, varscan2
- CDK12 | c.2350C>T p.R784* | Nonsense Mutation (SNP) | VAF 112/396 reads (28%) | catalogued as COSV71002558; called by muse, mutect2, varscan2
- CELSR1 | c.6487G>A p.V2163I | Missense Mutation (SNP) | VAF 145/618 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.047); catalogued as rs370135327; called by muse, mutect2, varscan2
- CEP126 | c.2096C>T p.T699M | Missense Mutation (SNP) | VAF 81/261 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as rs140786047; called by muse, mutect2, varscan2
- CFAP299 | c.448del p.R150Dfs*9 | Frame Shift Del (DEL) | VAF 52/196 reads (27%) | catalogued as rs761800837; called by mutect2, varscan2
- CLHC1 | c.690dup p.L231Ifs*16 | Frame Shift Ins (INS) | VAF 48/154 reads (31%) | catalogued as rs766798457; called by mutect2, pindel, varscan2
- COL11A1 | c.2142A>C p.K714N | Missense Mutation (SNP) | VAF 84/233 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100617967; called by muse, mutect2, varscan2
- COL6A3 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 391/523 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as rs200720222, COSV99797818; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPQ | c.447A>C p.E149D | Missense Mutation (SNP) | VAF 82/396 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as rs1363566291, COSV99610498; called by muse, mutect2, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 30/292 reads (10%) | catalogued as rs747832403; called by mutect2, pindel
- CRAT | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 124/406 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370724037; called by muse, varscan2
- CSMD1 | c.748T>G p.F250V | Missense Mutation (SNP) | VAF 122/355 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV101227380; called by muse, mutect2, varscan2
- CSRP2 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 96/285 reads (34%) | catalogued as rs561967313, COSV100222678, COSV104408634; called by muse, mutect2, varscan2
- CTNND1 | c.1372C>T p.R458* | Nonsense Mutation (SNP) | VAF 13/396 reads (3%) | catalogued as COSV62383997; called by muse, mutect2
- CWF19L2 | c.649T>G p.S217A | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV56508141; called by muse, mutect2, varscan2
- CYBA | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 134/437 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.515); catalogued as rs368862873; called by muse, mutect2, varscan2
- DAAM2 | c.2549A>G p.E850G | Missense Mutation (SNP) | VAF 76/309 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1043945554; called by muse, mutect2, varscan2
- DAPK1 | c.3822dup p.Y1275Vfs*64 | Frame Shift Ins (INS) | VAF 118/382 reads (31%) | catalogued as rs779681511; called by mutect2, varscan2
- DCSTAMP | c.710C>A p.P237H | Missense Mutation (SNP) | VAF 139/717 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV52575972; called by muse, mutect2, varscan2
- DDX1 | c.2165C>T p.A722V | Missense Mutation (SNP) | VAF 80/290 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.28); catalogued as rs556029393; called by muse, mutect2, varscan2
- DEFB112 | c.64A>C p.S22R | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.193); catalogued as rs139692238; called by muse, varscan2
- DHX37 | c.1582C>T p.R528W | Missense Mutation (SNP) | VAF 116/342 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs140218998; called by muse, mutect2, varscan2
- DICER1 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.187); catalogued as rs201298288, COSV100602150; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- DLST | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 128/390 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.086); catalogued as rs1211632994; called by muse, mutect2, varscan2
- DMBT1 | c.1625T>C p.L542S | Missense Mutation (SNP) | VAF 187/543 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199575931; called by muse, mutect2, varscan2
- DNAH7 | c.1037del p.K346Sfs*23 | Frame Shift Del (DEL) | VAF 84/229 reads (37%) | catalogued as rs761292636; called by mutect2, varscan2
- DNAJB12 | c.757G>A p.V253I (on ENST00000338820; = p.V219I on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/372 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.259); catalogued as rs143446268; called by muse, mutect2, varscan2
- DPEP3 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 194/525 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1208906485; called by muse, mutect2, varscan2
- DPF2 | c.178C>T p.R60* | Nonsense Mutation (SNP) | VAF 105/284 reads (37%) | catalogued as COSV52887798; called by muse, mutect2, varscan2
- DTNA | c.2077G>A p.D693N | Missense Mutation (SNP) | VAF 17/279 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.382); catalogued as rs778924121; called by muse, mutect2
- DYNC1H1 | c.2288C>T p.A763V | Missense Mutation (SNP) | VAF 17/418 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.453); catalogued as rs1358924141; ClinVar: uncertain significance; called by muse, mutect2
- DYNC1I2 | c.105del p.E36Kfs*34 | Frame Shift Del (DEL) | VAF 34/152 reads (22%) | catalogued as rs755197346; called by mutect2, varscan2
- EDNRB | c.512C>T p.P171L (on ENST00000377211 / NM_001201397.1; = p.P81L on NM_000115.5) | Missense Mutation (SNP) | VAF 42/576 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs756427784, COSV57524343; called by muse, mutect2
- EIF2AK1 | c.592del p.I198Sfs*2 | Frame Shift Del (DEL) | VAF 27/144 reads (19%) | catalogued as rs767715156, COSV104389006; called by mutect2, varscan2
- ELK1 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 266/690 reads (39%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.968); catalogued as COSV99902071; called by muse, mutect2, varscan2
- EP400 | c.4910G>A p.G1637D | Missense Mutation (SNP) | VAF 176/503 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100202533, COSV57781617; called by muse, mutect2, varscan2
- ESR1 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 210/803 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV52789479; called by muse, mutect2, varscan2
- ESX1 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 228/681 reads (33%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.022); catalogued as rs782334089; called by muse, mutect2, varscan2
- FAM234B | c.812G>A p.G271D | Missense Mutation (SNP) | VAF 107/317 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs140086625; called by muse, mutect2, varscan2
- FAM43B | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 212/568 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as rs1271698940; called by muse, mutect2, varscan2
- FAT3 | c.13325T>G p.L4442R | Missense Mutation (SNP) | VAF 127/341 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV53081604; called by mutect2, varscan2
- FEZ2 | c.32_33del p.Y11* | Frame Shift Del (DEL) | VAF 77/244 reads (32%) | catalogued as rs1474462096; called by mutect2, pindel, varscan2
- FSCN3 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 88/276 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs148605578; called by muse, mutect2, varscan2
- FSIP2 | c.19584del p.K6528Nfs*5 | Frame Shift Del (DEL) | VAF 125/231 reads (54%) | catalogued as rs781034813; called by mutect2, pindel, varscan2
- GABRA5 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 93/308 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV59475623; called by muse, mutect2, varscan2
- GIMAP1 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 168/473 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.036); catalogued as rs374968861, COSV56188394; called by muse, mutect2, varscan2
- GLG1 | c.2326G>A p.V776M | Missense Mutation (SNP) | VAF 102/309 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as rs758175120; called by muse, mutect2, varscan2
- GNB2 | c.784C>A p.L262I | Missense Mutation (SNP) | VAF 130/400 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99309902; called by muse, mutect2, varscan2
- GOLGA4 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 34/316 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.95); catalogued as rs778956577, COSV62710364; called by muse, mutect2, varscan2
- GREB1L | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 41/385 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52551926, COSV99339280; called by muse, mutect2, varscan2
- GRIA1 | c.1607C>A p.A536D | Missense Mutation (SNP) | VAF 90/150 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs138616362; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 38/244 reads (16%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIP1 | c.2377G>A p.D793N (on ENST00000359742 / NM_001379345.1; = p.D741N on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 173/502 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs767322707; called by muse, mutect2, varscan2
- GRK6 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 117/344 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs778598612, COSV62683485; called by muse, mutect2, varscan2
- HELZ2 | c.2602C>T p.R868W (on ENST00000467148 / NM_001037335.2; = p.R299W on NM_033405.3) | Missense Mutation (SNP) | VAF 86/483 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs951052670; called by muse, mutect2, varscan2
- HIC2 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 184/778 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs769081247, COSV68042180; called by muse, mutect2, varscan2
- HIF1A | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs188461135; called by muse, mutect2, varscan2
- HMGXB3 | c.3593C>T p.A1198V (on ENST00000613459; = p.A952V on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/308 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs183054657; called by muse, mutect2
- HRH4 | c.334C>T p.R112* | Nonsense Mutation (SNP) | VAF 53/226 reads (23%) | catalogued as rs778017267; called by muse, mutect2, varscan2
- IGF2BP3 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 102/320 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1056253827; called by muse, varscan2
- INPP4B | c.2621G>A p.R874Q | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT tolerated (0.96); PolyPhen benign (0.374); catalogued as rs751420268, COSV53720242, COSV53750965; called by muse, mutect2, varscan2
- IREB2 | c.627T>C p.P209= | Splice Region (SNP) | VAF 17/207 reads (8%) | catalogued as rs377051526; called by muse, mutect2
- IRX1 | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 139/530 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1291369713, COSV57361221; called by muse, mutect2, varscan2
- JAG1 | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 126/567 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs564566567, COSV54757001; called by muse, mutect2, varscan2
- KCNIP2 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 94/401 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); catalogued as COSV99493184; called by muse, mutect2, varscan2
- KIF21B | c.3673C>T p.R1225* | Nonsense Mutation (SNP) | VAF 46/321 reads (14%) | catalogued as rs147866695; called by muse, mutect2, varscan2
- KLHL24 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1236279281; called by muse, mutect2, varscan2
- KMT2E | c.5420C>T p.T1807I | Missense Mutation (SNP) | VAF 18/584 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs1224881584; called by muse, mutect2
- KNOP1 | c.957del p.G320Afs*8 | Frame Shift Del (DEL) | VAF 121/336 reads (36%) | catalogued as rs759734033, COSV54927684; called by mutect2, varscan2
- KRT33A | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 29/735 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs367617704; called by muse, mutect2
- KRTAP1-4 | c.228del p.C77Afs*4 | Frame Shift Del (DEL) | VAF 141/724 reads (19%) | catalogued as rs773983457; called by mutect2, pindel, varscan2
- KRTAP9-7 | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 249/699 reads (36%) | SIFT tolerated (0.08); catalogued as rs763663099; called by muse, mutect2, varscan2
- KSR2 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 227/666 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.548); catalogued as rs777786205; called by muse, mutect2, varscan2
- LARP1 | c.2827G>A p.A943T (on ENST00000518297 / NM_033551.3; = p.A866T on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 87/190 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV60424375; called by muse, mutect2, varscan2
- LCP2 | c.571del p.Q191Rfs*45 | Frame Shift Del (DEL) | VAF 19/110 reads (17%) | catalogued as rs769342570; called by mutect2, pindel, varscan2
- LEPR | c.2431C>A p.L811I | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100756245; called by muse, mutect2, varscan2
- LPP | c.1640C>T p.P547L | Missense Mutation (SNP) | VAF 99/543 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs762770149; called by muse, mutect2, varscan2
- LRP2 | c.9127C>T p.R3043C | Missense Mutation (SNP) | VAF 313/414 reads (76%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as rs760320712, COSV55560197; called by muse, mutect2, varscan2
- LRRC53 | c.2908dup p.T970Nfs*20 | Frame Shift Ins (INS) | VAF 49/210 reads (23%) | catalogued as rs1180095226; called by mutect2, pindel, varscan2
- LRRC56 | c.950A>G p.D317G | Missense Mutation (SNP) | VAF 185/532 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as rs1276728026; called by muse, mutect2, varscan2
- LRRIQ3 | c.1455A>C p.Q485H | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV63048858; called by muse, mutect2, varscan2
- LRRN1 | c.1751C>T p.T584M | Missense Mutation (SNP) | VAF 124/335 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780002625, COSV60015689; called by muse, mutect2, varscan2
- LTBP4 | c.1213G>A p.A405T (on ENST00000308370 / NM_001042544.1; = p.A368T on NM_003573.2) | Missense Mutation (SNP) | VAF 66/375 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1480507896, COSV99184103; called by muse, mutect2, varscan2
- MACF1 | c.7502G>A p.R2501H | Missense Mutation (SNP) | VAF 62/262 reads (24%) | catalogued as rs148092734, COSV57137913; called by muse, mutect2, varscan2
- MAP7D2 | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 186/480 reads (39%) | catalogued as rs967410039, COSV101107072; called by muse, mutect2, varscan2
- MAP9 | c.1700del p.K567Rfs*13 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as rs1215313075; called by mutect2, pindel, varscan2
- MCAT | c.737G>A p.R246Q (on ENST00000290429 / NM_173467.5; = p.T173= on NM_014507.3) | Missense Mutation (SNP) | VAF 51/318 reads (16%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs770360402; called by muse, mutect2, varscan2
- MED1 | c.1709del p.G570Vfs*9 | Frame Shift Del (DEL) | VAF 134/645 reads (21%) | catalogued as COSV56128100; called by mutect2, pindel, varscan2
- MKKS | c.1083dup p.H362Sfs*5 | Frame Shift Ins (INS) | VAF 82/393 reads (21%) | catalogued as COSV100726337; called by mutect2, varscan2
- MMP28 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 183/541 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as rs772090801; called by muse, mutect2, varscan2
- MPHOSPH8 | c.644del p.K215Sfs*7 | Frame Shift Del (DEL) | VAF 64/319 reads (20%) | catalogued as COSV100825205; called by mutect2, pindel, varscan2
- MPND | c.589G>A p.V197I | Missense Mutation (SNP) | VAF 145/446 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs749709699; called by muse, mutect2, varscan2
- MTSS1 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 297/654 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as rs200297766; called by muse, varscan2
- MUC16 | c.43007A>G p.Q14336R | Missense Mutation (SNP) | VAF 162/377 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.763); catalogued as rs756234381; called by muse, mutect2, varscan2
- NAB1 | c.403T>C p.C135R | Missense Mutation (SNP) | VAF 155/450 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.728); catalogued as rs1370418948; called by muse, mutect2, varscan2
- NACC2 | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 140/373 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs573716696; called by muse, mutect2, varscan2
- NBAS | c.2983G>A p.A995T | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV55734655; called by muse, mutect2, varscan2
- NBPF10 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.182); catalogued as COSV100744248; called by muse, mutect2, varscan2
- NDUFAF1 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 77/210 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs1420527153; called by muse, mutect2, varscan2
- NEK5 | c.120G>A p.M40I | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as rs768591441; called by muse, mutect2, varscan2
- NEUROD1 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 281/379 reads (74%) | SIFT tolerated (0.24); PolyPhen benign (0.153); catalogued as rs1409840273; called by muse, mutect2, varscan2
- NF1 | c.4525C>T p.R1509C (on ENST00000358273 / NM_001042492.3; = p.R1488C on NM_000267.3) | Missense Mutation (SNP) | VAF 82/291 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs864622348, COSV62194711; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NINL | c.3085G>A p.A1029T | Missense Mutation (SNP) | VAF 166/605 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs775433587; called by muse, mutect2, varscan2
- NLGN1 | c.2261T>G p.L754R | Missense Mutation (SNP) | VAF 140/543 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.956); catalogued as COSV100848798, COSV100850237, COSV64330434; called by muse, mutect2, varscan2
- NLK | c.576T>A p.F192L | Missense Mutation (SNP) | VAF 85/227 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.34); catalogued as COSV69407409, COSV69407806; called by muse, mutect2, varscan2
- NOLC1 | c.840del p.K280Nfs*3 | Frame Shift Del (DEL) | VAF 122/286 reads (43%) | catalogued as rs759637346; called by mutect2, varscan2
- NOMO1 | c.2995G>A p.E999K | Missense Mutation (SNP) | VAF 105/399 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.089); catalogued as rs771628678; called by muse, mutect2, varscan2
- NOTCH1 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 242/621 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1201407249; called by muse, mutect2, varscan2
- NOTCH2 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 20/531 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0.023); catalogued as rs782417990; called by muse, mutect2
- NTM | c.70C>A p.L24I | Missense Mutation (SNP) | VAF 130/378 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.63); catalogued as COSV66183174; called by muse, mutect2, varscan2
- NYAP2 | c.525G>A p.A175= | Splice Region (SNP) | VAF 111/162 reads (69%) | catalogued as rs756319896, COSV56002167; called by muse, mutect2, varscan2
- OGFOD1 | c.527G>T p.R176M | Missense Mutation (SNP) | VAF 81/261 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV60201135; called by muse, mutect2, varscan2
- OR2A7 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 108/934 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs1470924937; called by muse, mutect2, varscan2
- OR3A1 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 169/348 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs143631940; called by muse, mutect2, varscan2
- OTOGL | c.2797C>T p.R933* (on ENST00000547103; = p.R924* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 49/156 reads (31%) | catalogued as rs764511907, COSV72007609; called by muse, mutect2, varscan2
- OTUD6A | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 27/615 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1405885637, COSV57973317; called by muse, mutect2
- PAPLN | c.3179G>A p.R1060Q (on ENST00000554301; = p.R1033Q on NM_173462.4) | Missense Mutation (SNP) | VAF 212/570 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.07); catalogued as rs138138992; called by muse, mutect2, varscan2
- PCDHA11 | c.2386G>A p.G796R | Missense Mutation (SNP) | VAF 103/187 reads (55%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs782277615, COSV56480554; called by muse, mutect2, varscan2
- PCDHB2 | c.1880G>A p.R627H | Missense Mutation (SNP) | VAF 249/441 reads (56%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.563); catalogued as COSV99165351; called by muse, mutect2, varscan2
- PCDHB4 | c.1843G>A p.G615S | Missense Mutation (SNP) | VAF 256/426 reads (60%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.01); catalogued as COSV99522508; called by muse, mutect2, varscan2
- PCNT | c.947A>T p.E316V | Missense Mutation (SNP) | VAF 132/383 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs201194745; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDGFRB | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 121/215 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs368602685; called by muse, mutect2, varscan2
- PDZD7 | c.2122C>T p.R708C | Missense Mutation (SNP) | VAF 134/363 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.185); catalogued as rs1380221952; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHC2 | c.1745C>T p.A582V (on ENST00000257118 / NM_198040.2; = p.A47V on NM_004427.4) | Missense Mutation (SNP) | VAF 94/311 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1172925816, COSV57107231; called by muse, mutect2, varscan2
- PJA1 | c.1469T>C p.M490T (on ENST00000361478 / NM_145119.4; = p.M302T on NM_022368.5) | Missense Mutation (SNP) | VAF 19/544 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs1258409310; called by muse, mutect2
- PKN1 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 131/417 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54404761; called by muse, mutect2, varscan2
- PLA2G2A | c.75C>A p.F25L | Missense Mutation (SNP) | VAF 111/340 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.073); catalogued as COSV64286944; called by muse, mutect2, varscan2
- PPM1F | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 132/545 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs140855421; called by muse, mutect2, varscan2
- PPP1R14B | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 100/536 reads (19%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.133); catalogued as rs750523503, COSV54185926; called by muse, mutect2
- PRICKLE3 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 173/532 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1026876502; called by muse, mutect2, varscan2
- PRKDC | c.11809G>A p.V3937M | Missense Mutation (SNP) | VAF 58/917 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs56090750; called by muse, mutect2
- PRRT1 | c.485del p.G162Afs*3 | Frame Shift Del (DEL) | VAF 97/890 reads (11%) | catalogued as rs1334302334; called by mutect2, varscan2
- PRSS51 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1021856021; called by muse, mutect2, varscan2
- PSMD3 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 97/349 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs758424249; called by muse, mutect2, varscan2
- PTPN3 | c.2344G>A p.A782T | Missense Mutation (SNP) | VAF 96/318 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.526); catalogued as rs370019146; called by muse, mutect2, varscan2
- PYGL | c.2172G>T p.K724N | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV53588772; called by muse, mutect2, varscan2
- R3HDM2 | c.1102G>A p.G368S | Missense Mutation (SNP) | VAF 118/305 reads (39%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as rs370585554; called by muse, mutect2, varscan2
- RANBP17 | c.2986C>T p.R996W | Missense Mutation (SNP) | VAF 71/221 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as rs150124750; called by muse, mutect2, varscan2
- REXO1 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 233/623 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs749099928, COSV50084077; called by muse, mutect2, varscan2
- RIPK4 | c.1549C>T p.R517C (on ENST00000352483; = p.R469C on NM_020639.3) | Missense Mutation (SNP) | VAF 158/440 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.809); catalogued as rs771190743; called by muse, mutect2, varscan2
- RNF212 | c.815G>A p.G272D | Missense Mutation (SNP) | VAF 126/213 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs866180412; called by muse, varscan2
- RNF217 | c.1593dup p.Q532Tfs*16 | Frame Shift Ins (INS) | VAF 68/301 reads (23%) | catalogued as rs1413029182; called by mutect2, pindel, varscan2
- RYR3 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 54/269 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as rs201612485, COSV66780005; called by muse, mutect2, varscan2
- SCAMP3 | c.380del p.G127Afs*54 | Frame Shift Del (DEL) | VAF 107/333 reads (32%) | catalogued as COSV56945353; called by mutect2, varscan2
- SEC16A | c.1289G>A p.G430D | Missense Mutation (SNP) | VAF 157/510 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as rs918252177; called by muse, mutect2, varscan2
- SEC61B | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 57/370 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.017); catalogued as rs572201993; called by muse, mutect2, varscan2
- SEL1L | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 72/231 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.233); catalogued as rs758981227; called by muse, mutect2, varscan2
- SEMA3B | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 124/366 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs782216713, COSV57112820; called by muse, mutect2, varscan2
- SFT2D1 | c.117C>G p.I39M | Missense Mutation (SNP) | VAF 32/467 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV62277674; called by muse, mutect2
- SGO1 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 110/282 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as rs999124851, COSV55423844; called by muse, mutect2, varscan2
- SHISAL2A | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 89/247 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as COSV68979633; called by muse, mutect2, varscan2
- SHROOM2 | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 228/682 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.248); catalogued as rs144299681, COSV66607264; called by muse, mutect2, varscan2
- SIM1 | c.194G>A p.G65D | Missense Mutation (SNP) | VAF 155/565 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1449910709, COSV53489508; called by muse, mutect2, varscan2
- SLC22A23 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 250/473 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.058); catalogued as rs1441240227; called by muse, mutect2, varscan2
- SLC32A1 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 71/719 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as COSV54147178; called by muse, mutect2, varscan2
- SLC39A4 | c.413C>T p.P138L (on ENST00000301305 / NM_001374839.1; = p.P113L on NM_017767.3) | Missense Mutation (SNP) | VAF 145/1094 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs781929804, COSV52779064; called by muse, mutect2, varscan2
- SLC4A11 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 101/372 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs771135532, COSV66261411; called by muse, mutect2, varscan2
- SLC6A16 | c.1035A>C p.Q345H | Missense Mutation (SNP) | VAF 118/322 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.359); catalogued as COSV60028579, COSV60029438; called by muse, mutect2, varscan2
- SLC9A2 | c.1095G>A p.M365I | Missense Mutation (SNP) | VAF 80/299 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV52136611; called by muse, mutect2, varscan2
- SNX20 | c.754A>G p.R252G | Missense Mutation (SNP) | VAF 28/764 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs1353913523; called by muse, mutect2
- SPANXN2 | c.271T>C p.S91P | Missense Mutation (SNP) | VAF 241/694 reads (35%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.95); catalogued as COSV65128352, COSV65128658; called by muse, mutect2, varscan2
- SPEF2 | c.5372A>C p.K1791T | Missense Mutation (SNP) | VAF 56/216 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs546674187, COSV100289482, COSV57426909, COSV57427611; called by muse, mutect2, varscan2
- SRRM4 | c.1681C>T p.R561W | Missense Mutation (SNP) | VAF 214/613 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV57410378; called by muse, varscan2
- SRSF12 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 53/336 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as rs191899999; called by muse, mutect2, varscan2
- ST3GAL6 | c.738A>C p.K246N | Missense Mutation (SNP) | VAF 87/188 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV54580153, COSV54581667; called by muse, mutect2, varscan2
- STXBP6 | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 161/474 reads (34%) | catalogued as rs780359378, COSV60590461; called by muse, mutect2, varscan2
- SUPT20H | c.1115C>A p.A372E (on ENST00000350612 / NM_001014286.3; = p.A373E on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/309 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1468084846; called by muse, mutect2, varscan2
- SYNE1 | c.16940C>T p.A5647V (on ENST00000367255 / NM_182961.4; = p.A5576V on NM_033071.3) | Missense Mutation (SNP) | VAF 70/380 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as COSV55005681; called by muse, mutect2, varscan2
- TCF7 | c.463dup p.H155Pfs*37 | Frame Shift Ins (INS) | VAF 72/156 reads (46%) | catalogued as rs771602751; called by mutect2, varscan2
- TEAD1 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 54/398 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.122); catalogued as rs981365366, COSV57561413; called by muse, mutect2, varscan2
- TEX14 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 122/395 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); catalogued as rs374732278, COSV53615912; called by muse, mutect2, varscan2
- TGIF2LX | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 20/470 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.359); catalogued as COSV52213431; called by muse, mutect2
- TMC8 | c.1051G>T p.G351C | Missense Mutation (SNP) | VAF 20/516 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs1225450626, COSV59211715; called by muse, mutect2
- TNFSF15 | c.596A>C p.K199T | Missense Mutation (SNP) | VAF 148/394 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65010260; called by muse, mutect2, varscan2
- TNK2 | c.2323C>T p.P775S | Missense Mutation (SNP) | VAF 223/1040 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1178464753; called by muse, mutect2, varscan2
- TRAK1 | c.1147C>T p.R383C (on ENST00000327628 / NM_001349247.2; = p.R325C on NM_014965.5) | Missense Mutation (SNP) | VAF 142/365 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58262495; called by muse, mutect2, varscan2
- TRHDE | c.1758A>C p.E586D | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV53838055; called by muse, mutect2, varscan2
- TRIM28 | c.1771C>T p.R591C | Missense Mutation (SNP) | VAF 177/504 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs750720339, COSV53401460; called by muse, mutect2, varscan2
- TRIM64B | c.1094C>A p.A365D | Missense Mutation (SNP) | VAF 140/757 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.297); catalogued as COSV61694052; called by muse, mutect2, varscan2
- TRIM68 | c.522G>A p.K174= | Splice Region (SNP) | VAF 16/349 reads (5%) | catalogued as rs1321352644; called by muse, mutect2
- TRIP6 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 196/551 reads (36%) | SIFT tolerated (0.75); PolyPhen benign (0.342); catalogued as rs755248014; called by muse, mutect2, varscan2
- TTI1 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 114/421 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs372043570, COSV100989765; called by muse, mutect2, varscan2
- TTLL2 | c.1460A>G p.Q487R | Missense Mutation (SNP) | VAF 137/502 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV53444075; called by muse, mutect2, varscan2
- USP32 | c.1999C>T p.R667C | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766194250, COSV100341818; called by muse, varscan2
- VAV1 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 76/409 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs771269172, COSV58378743; called by muse, mutect2, varscan2
- VEGFB | c.386del p.K129Rfs*5 | Frame Shift Del (DEL) | VAF 34/189 reads (18%) | catalogued as rs747177567, COSV100374813; called by mutect2, varscan2
- WDTC1 | c.868dup p.E290Gfs*7 | Frame Shift Ins (INS) | VAF 82/230 reads (36%) | catalogued as rs747972901; called by mutect2, varscan2
- ZBTB2 | c.1444C>T p.R482* | Nonsense Mutation (SNP) | VAF 49/444 reads (11%) | catalogued as COSV57311689, COSV57311951; called by muse, mutect2, varscan2
- ZMYM3 | c.3784C>T p.R1262C | Missense Mutation (SNP) | VAF 149/424 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs759704463; called by muse, mutect2, varscan2
- ZNF285 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 110/300 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as rs765848183, COSV58410103; called by muse, mutect2, varscan2
- ZNF43 | c.2174A>G p.K725R | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.159); catalogued as rs765494319, COSV61686480; called by muse, mutect2, varscan2
- ZNF438 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 130/409 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs775935719, COSV59192635; called by muse, mutect2, varscan2
- ZNF492 | c.1356A>C p.E452D | Missense Mutation (SNP) | VAF 86/272 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.684); catalogued as COSV71761794; called by muse, mutect2, varscan2
- ZNF587 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 44/366 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1284670040, COSV57147902; called by muse, varscan2
- ZNF729 | c.3052A>G p.K1018E | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1346885174; called by muse, mutect2, varscan2
- ABCC3 | c.3682C>A p.L1228I | Missense Mutation (SNP) | VAF 104/343 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ABCC5 | c.3807A>C p.K1269N | Missense Mutation (SNP) | VAF 99/504 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- ADAMTS16 | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 107/427 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAMTS3 | c.1217T>C p.M406T | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ALB | c.779C>T p.T260I | Missense Mutation (SNP) | VAF 28/361 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.066); called by muse, mutect2
- ALG11 | c.1262dup p.L424Afs*2 | Frame Shift Ins (INS) | VAF 100/508 reads (20%) | called by mutect2, pindel, varscan2
- ANKRD30BL | c.605A>C p.K202T | Missense Mutation (SNP) | VAF 111/159 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- ANKRD50 | c.1196G>A p.G399E | Missense Mutation (SNP) | VAF 92/244 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- APC | c.4778dup p.P1594Afs*38 | Frame Shift Ins (INS) | VAF 122/258 reads (47%) | called by mutect2, pindel, varscan2
- AQP10 | c.596T>C p.L199P | Missense Mutation (SNP) | VAF 92/479 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ARX | c.1156C>G p.R386G | Missense Mutation (SNP) | VAF 30/736 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2
- ARX | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- ATP10A | c.595A>G p.N199D | Missense Mutation (SNP) | VAF 134/395 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ATP1A1 | c.1819C>T p.R607* | Nonsense Mutation (SNP) | VAF 112/278 reads (40%) | called by muse, mutect2, varscan2
- ATPAF1 | c.212_217dup p.Q72_A73insVQ (on ENST00000574428; = p.Q95_A96insVQ on NM_022745.4) | In Frame Ins (INS) | VAF 104/307 reads (34%) | called by mutect2, pindel, varscan2
- ATXN1 | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 194/743 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ATXN7L3 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 85/262 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, varscan2
- AXIN1 | c.1326del p.A443Lfs*37 | Frame Shift Del (DEL) | VAF 199/741 reads (27%) | called by mutect2, pindel, varscan2
- BAZ1B | c.3298C>T p.L1100F | Missense Mutation (SNP) | VAF 92/307 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- C8A | c.420C>A p.C140* | Nonsense Mutation (SNP) | VAF 105/368 reads (29%) | called by muse, mutect2, varscan2
- CABLES1 | c.203T>C p.F68S | Missense Mutation (SNP) | VAF 146/514 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by mutect2, varscan2
- CACNA1G | c.5258T>C p.L1753S | Missense Mutation (SNP) | VAF 92/346 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA1H | c.5570C>T p.A1857V | Missense Mutation (SNP) | VAF 189/567 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CASC3 | c.494del p.K165Rfs*114 | Frame Shift Del (DEL) | VAF 102/412 reads (25%) | called by mutect2, pindel, varscan2
- CCDC168 | c.1874C>A p.P625H | Missense Mutation (SNP) | VAF 64/278 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- CCT3 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 64/247 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CDH11 | c.2239G>T p.G747C | Missense Mutation (SNP) | VAF 21/476 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CERKL | c.1488del p.V497Ffs*29 (on ENST00000339098 / NM_001030311.2; = p.V471Ffs*29 on NM_201548.5) | Frame Shift Del (DEL) | VAF 21/197 reads (11%) | called by mutect2, pindel, varscan2
- CFAP54 | c.3996del p.K1332Nfs*13 | Frame Shift Del (DEL) | VAF 16/161 reads (10%) | called by mutect2, pindel
- CFAP58 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 105/360 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CHD4 | c.4095_4097del p.D1365del (on ENST00000357008 / NM_001363606.2; = p.D1378del on NM_001273.5) | In Frame Del (DEL) | VAF 86/302 reads (28%) | called by pindel, varscan2
- CNTN3 | c.1988T>G p.V663G | Missense Mutation (SNP) | VAF 113/319 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- COL19A1 | c.269A>C p.K90T | Missense Mutation (SNP) | VAF 71/240 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL23A1 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 78/248 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL24A1 | c.2345del p.N782Tfs*57 | Frame Shift Del (DEL) | VAF 61/253 reads (24%) | called by pindel, varscan2
- COL2A1 | c.2560G>A p.A854T | Missense Mutation (SNP) | VAF 125/400 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- COPB2 | c.1266del p.K422Nfs*23 | Frame Shift Del (DEL) | VAF 54/170 reads (32%) | called by mutect2, varscan2
- CPXM2 | c.1777A>C p.S593R | Missense Mutation (SNP) | VAF 99/232 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- CREB3 | c.1052G>T p.R351M | Missense Mutation (SNP) | VAF 111/307 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- CRTAC1 | c.1735A>G p.N579D | Missense Mutation (SNP) | VAF 16/493 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- CSMD1 | c.7599A>C p.Q2533H (on ENST00000520002; = p.Q2532H on NM_033225.6) | Missense Mutation (SNP) | VAF 130/351 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- CXCL10 | c.72_75del p.S25Efs*20 | Frame Shift Del (DEL) | VAF 50/167 reads (30%) | called by mutect2, pindel, varscan2
- DENND2C | c.2431G>T p.D811Y (on ENST00000393274 / NM_001256404.2; = p.D754Y on NM_198459.4) | Missense Mutation (SNP) | VAF 68/162 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DENND2C | c.427T>G p.F143V | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DMRT3 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 179/479 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DNA2 | c.527dup p.E177Rfs*29 | Frame Shift Ins (INS) | VAF 112/331 reads (34%) | called by mutect2, pindel, varscan2
- DNAAF2 | c.680C>A p.P227H | Missense Mutation (SNP) | VAF 18/598 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- DNAH14 | c.1631C>T p.A544V (on ENST00000445597; = p.A525V on NM_001367479.1) | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DOP1A | c.6322A>G p.K2108E | Missense Mutation (SNP) | VAF 38/424 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- DSG3 | c.2417G>A p.G806D | Missense Mutation (SNP) | VAF 97/420 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ELAPOR1 | c.1004A>G p.Y335C | Missense Mutation (SNP) | VAF 20/370 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); called by muse, mutect2
- ELF1 | c.5C>A p.A2D | Missense Mutation (SNP) | VAF 77/331 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- ELOVL1 | c.655T>C p.Y219H | Missense Mutation (SNP) | VAF 82/250 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- EPN1 | c.939del p.T314Rfs*128 (on ENST00000270460 / NM_001321263.1; = p.T289Rfs*127 on NM_013333.3) | Frame Shift Del (DEL) | VAF 237/644 reads (37%) | called by mutect2, varscan2
- ERG | c.1318C>G p.P440A (on ENST00000398919 / NM_001243428.1; = p.P416A on NM_004449.4) | Missense Mutation (SNP) | VAF 171/477 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- EVI2B | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 44/321 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EVPL | c.407T>C p.L136P | Missense Mutation (SNP) | VAF 73/412 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EXOSC6 | c.770A>G p.Q257R | Missense Mutation (SNP) | VAF 29/631 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2
- FAM120C | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 210/544 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- FAT4 | c.11719C>A p.L3907M | Missense Mutation (SNP) | VAF 72/285 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FGF10 | c.10T>C p.W4R | Missense Mutation (SNP) | VAF 11/380 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- FMO5 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 89/287 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FNDC3A | c.1574A>G p.Y525C (on ENST00000492622 / NM_001079673.2; = p.Y469C on NM_014923.5) | Missense Mutation (SNP) | VAF 71/307 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FOXE1 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 195/483 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- FRG2C | c.85T>G p.F29V | Missense Mutation (SNP) | VAF 100/1294 reads (8%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.943); called by muse, mutect2
- GIGYF1 | c.2342G>T p.G781V | Missense Mutation (SNP) | VAF 190/578 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- GIT2 | c.761A>T p.D254V | Missense Mutation (SNP) | VAF 56/205 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- GPR158 | c.706_709dup p.R237Pfs*60 | Frame Shift Ins (INS) | VAF 200/590 reads (34%) | called by mutect2, pindel, varscan2
- GRM6 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 169/527 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- HOXA3 | c.446C>A p.P149H | Missense Mutation (SNP) | VAF 161/477 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- HOXC12 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 48/450 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IDH2 | c.1149del p.K384Sfs*28 | Frame Shift Del (DEL) | VAF 125/370 reads (34%) | called by mutect2, varscan2
- ITGAL | c.1886T>A p.I629N | Missense Mutation (SNP) | VAF 140/381 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JPH4 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 120/587 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- KCNA5 | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 48/679 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- KIF20B | c.3223dup p.S1075Kfs*5 (on ENST00000371728 / NM_001284259.2; = p.S1035Kfs*5 on NM_016195.4) | Frame Shift Ins (INS) | VAF 66/234 reads (28%) | called by mutect2, varscan2
- KRT2 | c.155del p.G52Afs*84 | Frame Shift Del (DEL) | VAF 156/506 reads (31%) | called by mutect2, pindel, varscan2
- LIMS2 | c.650G>T p.W217L (on ENST00000355119 / NM_001161403.3; = p.W241L on NM_017980.4) | Missense Mutation (SNP) | VAF 75/332 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- LLGL1 | c.1423A>G p.T475A | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- LPCAT2 | c.1046T>G p.I349S | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- LRP1 | c.2814del p.N939Tfs*41 | Frame Shift Del (DEL) | VAF 138/396 reads (35%) | called by mutect2, pindel, varscan2
- LRP10 | c.1802A>C p.E601A | Missense Mutation (SNP) | VAF 244/653 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- LRP12 | c.1795T>A p.S599T | Missense Mutation (SNP) | VAF 96/474 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- LRP12 | c.548G>T p.W183L | Missense Mutation (SNP) | VAF 46/357 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LRP1B | c.680T>A p.L227Q | Missense Mutation (SNP) | VAF 133/170 reads (78%) | SIFT tolerated (0.13); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- LRRC43 | c.685C>A p.L229M | Missense Mutation (SNP) | VAF 83/251 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC9 | c.2505del p.F835Lfs*35 | Frame Shift Del (DEL) | VAF 67/222 reads (30%) | called by mutect2, pindel, varscan2
- LSR | c.1258C>T p.P420S (on ENST00000361790; = p.P401S on NM_015925.6) | Missense Mutation (SNP) | VAF 117/357 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- MAGEE1 | c.1631T>G p.F544C | Missense Mutation (SNP) | VAF 23/596 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MAGT1 | c.553A>C p.N185H (on ENST00000618282 / NM_001367916.1; = p.N217H on NM_032121.5) | Missense Mutation (SNP) | VAF 79/251 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MAP4K3 | c.1076del p.L359Wfs*31 | Frame Shift Del (DEL) | VAF 78/244 reads (32%) | called by mutect2, pindel, varscan2
- MARCHF7 | c.1267_1268del p.I423Ffs*2 | Frame Shift Del (DEL) | VAF 90/338 reads (27%) | called by pindel, varscan2
- MED23 | c.370A>G p.K124E | Missense Mutation (SNP) | VAF 88/352 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- METTL7B | c.5A>G p.D2G | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- MFSD6 | c.2171A>T p.Q724L | Missense Mutation (SNP) | VAF 96/134 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- MFSD8 | c.1344A>C p.K448N | Missense Mutation (SNP) | VAF 149/395 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MMP13 | c.898del p.T300Qfs*2 | Frame Shift Del (DEL) | VAF 80/266 reads (30%) | called by mutect2, pindel, varscan2
- MPIG6B | c.589C>T p.P197S (on ENST00000649779 / NM_138272.3; = p.A203V on NM_025260.4) | Missense Mutation (SNP) | VAF 239/901 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- MSL1 | c.159G>T p.K53N | Missense Mutation (SNP) | VAF 214/867 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- MTMR11 | c.2119del p.D707Ifs*36 | Frame Shift Del (DEL) | VAF 33/235 reads (14%) | called by mutect2, pindel, varscan2
- MUC4 | c.14839G>A p.A4947T (on ENST00000463781 / NM_018406.7; = p.A711T on NM_004532.6) | Missense Mutation (SNP) | VAF 140/754 reads (19%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MVB12B | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 128/328 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MYH11 | c.4896G>T p.Q1632H | Missense Mutation (SNP) | VAF 19/585 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.044); called by muse, mutect2
- MYO15B | c.2982G>T p.E994D | Missense Mutation (SNP) | VAF 94/283 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- MYO5A | c.3445C>A p.P1149T | Missense Mutation (SNP) | VAF 31/224 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by mutect2, varscan2
- NAALAD2 | c.1242A>C p.E414D | Missense Mutation (SNP) | VAF 115/329 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- NDST4 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 87/300 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- NDUFA2 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 17/314 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.891); called by muse, mutect2
- NFKBIE | c.989C>T p.A330V (on ENST00000275015; = p.A191V on NM_004556.3) | Missense Mutation (SNP) | VAF 71/625 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NIPA2 | c.97_98del p.K33Gfs*22 | Frame Shift Del (DEL) | VAF 69/272 reads (25%) | called by mutect2, pindel, varscan2
- NLGN1 | c.1424T>G p.L475R | Missense Mutation (SNP) | VAF 133/498 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NOTCH2 | c.1510G>A p.V504M | Missense Mutation (SNP) | VAF 114/316 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NR2F6 | c.470G>A p.G157D | Missense Mutation (SNP) | VAF 212/574 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- NRXN3 | c.74G>A p.C25Y | Missense Mutation (SNP) | VAF 183/533 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- NSMAF | c.2374C>A p.L792I | Missense Mutation (SNP) | VAF 71/612 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NSMF | c.602G>T p.R201M | Missense Mutation (SNP) | VAF 138/440 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NUP155 | c.986A>G p.N329S (on ENST00000231498 / NM_153485.3; = p.N270S on NM_004298.4) | Missense Mutation (SNP) | VAF 97/352 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- OCIAD1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 80/130 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- OOEP | c.400T>G p.L134V | Missense Mutation (SNP) | VAF 15/475 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- PALM2AKAP2 | c.1965_1966del p.Q658Afs*12 (on ENST00000259318 / NM_001136562.3; = p.Q889Afs*12 on NM_007203.5) | Frame Shift Del (DEL) | VAF 86/466 reads (18%) | called by pindel, varscan2
- PCDH11X | c.1629dup p.D544Rfs*2 | Frame Shift Ins (INS) | VAF 40/351 reads (11%) | called by mutect2, pindel, varscan2
- PHF23 | c.23C>G p.P8R | Missense Mutation (SNP) | VAF 115/189 reads (61%) | SIFT tolerated (0.43); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- PHLPP1 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 71/240 reads (30%) | SIFT deleterious, low confidence (0); called by muse, varscan2
- PKD2L1 | c.1613dup p.A539Cfs*24 | Frame Shift Ins (INS) | VAF 123/373 reads (33%) | called by mutect2, pindel, varscan2
- PKHD1 | c.4357C>T p.P1453S | Missense Mutation (SNP) | VAF 55/683 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.027); called by muse, mutect2
- PKN3 | c.1392del p.C465Afs*43 | Frame Shift Del (DEL) | VAF 205/539 reads (38%) | called by mutect2, varscan2
- PLCXD2 | c.807del p.R270Efs*2 | Frame Shift Del (DEL) | VAF 135/421 reads (32%) | called by mutect2, pindel, varscan2
- PNMA6F | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 163/531 reads (31%) | SIFT tolerated (0.27); called by muse, mutect2, varscan2
- POU5F1 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 102/984 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PPP2R3B | c.1165del p.T389Hfs*70 | Frame Shift Del (DEL) | VAF 137/441 reads (31%) | called by mutect2, pindel, varscan2
- PRDM10 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 179/556 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRKAA1 | c.643C>T p.L215F | Missense Mutation (SNP) | VAF 61/307 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRMT9 | c.2131_2133del p.E711del | In Frame Del (DEL) | VAF 38/264 reads (14%) | called by pindel, varscan2
- PTCHD3 | c.1081A>C p.K361Q | Missense Mutation (SNP) | VAF 99/287 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- PTPRH | c.943C>A p.L315M | Missense Mutation (SNP) | VAF 64/396 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- PTPRQ | c.4532T>G p.L1511R (on ENST00000616559; = p.L1469R on NM_001145026.2) | Missense Mutation (SNP) | VAF 104/276 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PTPRT | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 81/397 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PTRH2 | c.253C>A p.Q85K | Missense Mutation (SNP) | VAF 23/431 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PYGL | c.2394G>T p.W798C | Missense Mutation (SNP) | VAF 66/223 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASSF8 | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 41/399 reads (10%) | called by muse, mutect2, varscan2
- RBFOX2 | c.215del p.G72Dfs*58 | Frame Shift Del (DEL) | VAF 138/605 reads (23%) | called by mutect2, pindel, varscan2
- RGL2 | c.45del p.G17Efs*4 | Frame Shift Del (DEL) | VAF 123/569 reads (22%) | called by mutect2, pindel, varscan2
- RIPOR1 | c.1702A>T p.S568C (on ENST00000379312 / NM_001193522.2; = p.S564C on NM_024519.4) | Missense Mutation (SNP) | VAF 169/493 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- RRBP1 | c.1562del p.K521Rfs*40 | Frame Shift Del (DEL) | VAF 102/612 reads (17%) | called by pindel, varscan2
- SAFB | c.1642G>T p.E548* | Nonsense Mutation (SNP) | VAF 128/376 reads (34%) | called by muse, mutect2, varscan2
- SCART1 | c.683-1G>T p.X228_splice | Splice Site (SNP) | VAF 155/359 reads (43%) | called by muse, mutect2, varscan2
- SETBP1 | c.4651G>A p.G1551R | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- SETD5 | c.3022dup p.D1008Gfs*2 | Frame Shift Ins (INS) | VAF 95/295 reads (32%) | called by mutect2, pindel, varscan2
- SH2D3C | c.1788G>T p.K596N (on ENST00000314830 / NM_170600.3; = p.K439N on NM_005489.4) | Missense Mutation (SNP) | VAF 106/299 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- SIRT1 | c.793T>C p.S265P | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC15A2 | c.1652_1653del p.V551Afs*11 | Frame Shift Del (DEL) | VAF 38/206 reads (18%) | called by pindel, varscan2
- SLC19A1 | c.1586del p.P529Rfs*9 | Frame Shift Del (DEL) | VAF 184/657 reads (28%) | called by mutect2, pindel, varscan2
- SLIT2 | c.2687T>C p.L896P | Missense Mutation (SNP) | VAF 92/144 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SLITRK3 | c.1928A>G p.E643G | Missense Mutation (SNP) | VAF 162/629 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA16 | c.30G>T p.E10D | Missense Mutation (SNP) | VAF 73/354 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- SPCS3 | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 67/180 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- ST18 | c.1180del p.H394Tfs*30 | Frame Shift Del (DEL) | VAF 87/680 reads (13%) | called by mutect2, varscan2
- STUB1 | c.646del p.S216Lfs*24 | Frame Shift Del (DEL) | VAF 93/378 reads (25%) | called by mutect2, pindel, varscan2
- SYNE1 | c.5136C>A p.F1712L (on ENST00000367255 / NM_182961.4; = p.F1719L on NM_033071.3) | Missense Mutation (SNP) | VAF 83/321 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAF8 | c.698A>G p.E233G | Missense Mutation (SNP) | VAF 18/654 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2
- TBC1D5 | c.1202T>C p.V401A | Missense Mutation (SNP) | VAF 83/241 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- TBC1D5 | c.817C>T p.Q273* | Nonsense Mutation (SNP) | VAF 44/169 reads (26%) | called by muse, mutect2, varscan2
- TDRD15 | c.1899del p.D634Mfs*6 | Frame Shift Del (DEL) | VAF 44/189 reads (23%) | called by mutect2, pindel, varscan2
- TDRP | c.341T>G p.L114R | Missense Mutation (SNP) | VAF 117/372 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- TEAD3 | c.892A>G p.K298E | Missense Mutation (SNP) | VAF 95/364 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TET3 | c.3920G>A p.G1307E | Missense Mutation (SNP) | VAF 252/368 reads (68%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.562); called by muse, varscan2
- TET3 | c.3922C>T p.H1308Y | Missense Mutation (SNP) | VAF 255/373 reads (68%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.575); called by muse, varscan2
- THBS1 | c.608del p.G203Afs*13 | Frame Shift Del (DEL) | VAF 115/402 reads (29%) | called by mutect2, pindel, varscan2
- THOC2 | c.1037T>G p.L346R | Missense Mutation (SNP) | VAF 81/214 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TLL1 | c.3037A>C p.K1013Q | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- TMEM151B | c.11del p.P4Lfs*84 | Frame Shift Del (DEL) | VAF 61/373 reads (16%) | called by mutect2, pindel, varscan2
- TNRC18 | c.7472del p.G2491Afs*9 | Frame Shift Del (DEL) | VAF 130/462 reads (28%) | called by mutect2, varscan2
- TPTE | c.963A>C p.E321D (on ENST00000618007 / NM_199261.4; = p.E303D on NM_199259.4) | Missense Mutation (SNP) | VAF 72/613 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TRAPPC10 | c.2770-1G>T p.X924_splice | Splice Site (SNP) | VAF 60/177 reads (34%) | called by muse, mutect2, varscan2
- TRIML2 | c.1016T>C p.V339A | Missense Mutation (SNP) | VAF 170/497 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- TRRAP | c.7873G>A p.A2625T (on ENST00000359863 / NM_001244580.1; = p.A2607T on NM_003496.3) | Missense Mutation (SNP) | VAF 145/384 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- TSHZ1 | c.1268G>A p.S423N (on ENST00000580243 / NM_001308210.2; = p.S378N on NM_005786.6) | Missense Mutation (SNP) | VAF 135/290 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- TSHZ2 | c.1398del p.E467Kfs*13 | Frame Shift Del (DEL) | VAF 49/388 reads (13%) | called by mutect2, pindel, varscan2
- TSPAN18 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 129/431 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.46444G>A p.A15482T (on ENST00000591111; = p.A8058T on NM_003319.4) | Missense Mutation (SNP) | VAF 12/330 reads (4%) | PolyPhen probably damaging (0.998); called by muse, mutect2
- TXNDC5 | c.472del p.Q158Rfs*11 | Frame Shift Del (DEL) | VAF 119/418 reads (28%) | called by mutect2, pindel, varscan2
- UNC5C | c.902G>T p.G301V | Missense Mutation (SNP) | VAF 98/335 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USH2A | c.3042T>A p.C1014* | Nonsense Mutation (SNP) | VAF 100/306 reads (33%) | called by muse, mutect2, varscan2
- USP9X | c.82del p.L28Sfs*51 | Frame Shift Del (DEL) | VAF 57/666 reads (9%) | called by mutect2, pindel
- WASF3 | c.1109del p.P370Rfs*55 | Frame Shift Del (DEL) | VAF 152/625 reads (24%) | called by mutect2, varscan2
- ZBTB20 | c.470T>C p.F157S (on ENST00000474710 / NM_001164342.2; = p.F84S on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/470 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ZBTB46 | c.392T>C p.I131T | Missense Mutation (SNP) | VAF 146/636 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZC3H13 | c.3018del p.K1006Nfs*31 | Frame Shift Del (DEL) | VAF 54/248 reads (22%) | called by mutect2, varscan2
- ZMYM3 | c.3220T>C p.W1074R | Missense Mutation (SNP) | VAF 160/485 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF208 | c.3130C>A p.L1044I | Missense Mutation (SNP) | VAF 160/411 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- ZNF217 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 126/482 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ZNF316 | c.2362G>A p.A788T | Missense Mutation (SNP) | VAF 35/614 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.537); called by muse, mutect2
- ZNF43 | c.1586A>C p.K529T | Missense Mutation (SNP) | VAF 92/281 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZNF506 | c.345del p.G116Afs*5 | Frame Shift Del (DEL) | VAF 58/166 reads (35%) | called by mutect2, varscan2
- ZNF521 | c.3881A>G p.K1294R | Missense Mutation (SNP) | VAF 77/337 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF592 | c.1884_1886del p.N628del | In Frame Del (DEL) | VAF 100/350 reads (29%) | called by pindel, varscan2
- ZNRF3 | c.1550del p.P517Rfs*53 (on ENST00000544604 / NM_001206998.2; = p.P417Rfs*53 on NM_032173.3) | Frame Shift Del (DEL) | VAF 182/790 reads (23%) | called by pindel, varscan2
- ZSCAN31 | c.1003A>G p.S335G | Missense Mutation (SNP) | VAF 48/504 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.114); called by muse, mutect2
- AAR2 | c.714T>C p.T238= | Silent (SNP) | VAF 27/602 reads (4%) | called by muse, mutect2
- AGAP1 | c.1044T>C p.I348= | Silent (SNP) | VAF 13/379 reads (3%) | called by muse, mutect2
- ARHGAP39 | c.1650C>T p.A550= | Silent (SNP) | VAF 212/1084 reads (20%) | catalogued as rs962223737; called by muse, mutect2, varscan2
- ARSG | c.1464C>T p.D488= | Silent (SNP) | VAF 125/418 reads (30%) | catalogued as rs771398663; called by muse, mutect2, varscan2
- ATF6 | c.786C>A p.V262= | Silent (SNP) | VAF 112/396 reads (28%) | catalogued as COSV63410039; called by muse, mutect2, varscan2
- ATG2A | c.1779G>A p.A593= | Silent (SNP) | VAF 203/546 reads (37%) | catalogued as rs753940770, COSV65969158; called by muse, mutect2, varscan2
- BPNT1 | c.903T>A p.S301= | Silent (SNP) | VAF 99/293 reads (34%) | called by muse, mutect2, varscan2
- BRD9 | c.885A>T p.A295= | Silent (SNP) | VAF 194/693 reads (28%) | called by muse, mutect2, varscan2
- CCT6B | c.33T>A p.A11= | Silent (SNP) | VAF 137/371 reads (37%) | called by muse, mutect2, varscan2
- CD2BP2 | c.30C>T p.G10= | Silent (SNP) | VAF 127/349 reads (36%) | catalogued as rs914839387; called by muse, mutect2, varscan2
- CDH11 | c.627G>A p.S209= | Silent (SNP) | VAF 85/216 reads (39%) | catalogued as rs367922113; called by muse, mutect2, varscan2
- CEP55 | c.570G>A p.Q190= | Silent (SNP) | VAF 109/285 reads (38%) | catalogued as COSV65186134; called by muse, mutect2, varscan2
- CERS3 | c.831T>C p.I277= | Silent (SNP) | VAF 93/213 reads (44%) | called by muse, mutect2, varscan2
- CFAP47 | c.5382T>C p.V1794= | Silent (SNP) | VAF 55/192 reads (29%) | called by muse, mutect2, varscan2
- CFAP57 | c.720C>T p.T240= | Silent (SNP) | VAF 97/276 reads (35%) | catalogued as COSV100993953, COSV65264226; called by muse, mutect2, varscan2
- CHAD | c.537G>A p.S179= | Silent (SNP) | VAF 32/561 reads (6%) | catalogued as rs867397902; called by muse, mutect2
- CNTN4 | c.990A>G p.E330= | Silent (SNP) | VAF 72/222 reads (32%) | called by muse, mutect2, varscan2
- COL27A1 | c.1785G>A p.A595= | Silent (SNP) | VAF 76/548 reads (14%) | catalogued as rs781558892, COSV61931796; called by muse, mutect2, varscan2
- COX10 | c.885G>A p.P295= | Silent (SNP) | VAF 59/433 reads (14%) | catalogued as rs553764464, COSV55409208; called by muse, mutect2, varscan2
- CRACDL | c.1104C>T p.G368= | Silent (SNP) | VAF 26/598 reads (4%) | called by muse, mutect2
- CXCR6 | c.78C>T p.F26= | Silent (SNP) | VAF 46/333 reads (14%) | catalogued as rs1310196282; called by muse, mutect2, varscan2
- DIAPH3 | c.1737T>G p.P579= (on ENST00000400324 / NM_001042517.2; = p.P316= on NM_030932.3) | Silent (SNP) | VAF 20/514 reads (4%) | called by muse, mutect2
- DMWD | c.1527T>C p.G509= | Silent (SNP) | VAF 20/590 reads (3%) | called by muse, mutect2
- DNAH12 | c.3324A>G p.V1108= (on ENST00000351747; = p.V1131= on NM_001366028.2) | Silent (SNP) | VAF 101/314 reads (32%) | called by muse, mutect2, varscan2
- DSE | c.1914C>T p.G638= | Silent (SNP) | VAF 114/443 reads (26%) | catalogued as rs200111859; called by muse, mutect2, varscan2
- EDEM1 | c.537A>G p.L179= | Silent (SNP) | VAF 51/209 reads (24%) | catalogued as rs748972552; called by muse, mutect2, varscan2
- EGFR | c.1410C>T p.C470= | Silent (SNP) | VAF 16/305 reads (5%) | called by muse, mutect2
- ELANE | c.417G>T p.P139= | Silent (SNP) | VAF 234/585 reads (40%) | called by muse, mutect2, varscan2
- ELMO1 | c.297C>A p.A99= | Silent (SNP) | VAF 122/366 reads (33%) | catalogued as COSV100164485; called by muse, mutect2, varscan2
- EP400 | c.1665G>A p.P555= | Silent (SNP) | VAF 164/499 reads (33%) | catalogued as rs773594607; called by muse, mutect2, varscan2
- FAT2 | c.5083A>C p.R1695= | Silent (SNP) | VAF 93/155 reads (60%) | called by muse, mutect2, varscan2
- FXR1 | c.939G>T p.V313= | Silent (SNP) | VAF 51/341 reads (15%) | called by muse, mutect2, varscan2
- GAB4 | c.780T>C p.V260= | Silent (SNP) | VAF 118/467 reads (25%) | called by muse, mutect2, varscan2
- GABBR2 | c.99G>T p.L33= | Silent (SNP) | VAF 119/390 reads (31%) | called by muse, mutect2, varscan2
- GALR1 | c.636G>A p.P212= | Silent (SNP) | VAF 16/234 reads (7%) | called by muse, mutect2
- GRM1 | c.1692T>G p.A564= | Silent (SNP) | VAF 98/439 reads (22%) | called by muse, mutect2, varscan2
- GZF1 | c.1608G>A p.Q536= | Silent (SNP) | VAF 75/283 reads (27%) | called by muse, mutect2, varscan2
- H2AJ | c.349C>T p.L117= | Silent (SNP) | VAF 15/357 reads (4%) | called by muse, mutect2
- H2BC6 | c.6T>A p.P2= | Silent (SNP) | VAF 82/204 reads (40%) | called by muse, mutect2, varscan2
- H3C12 | c.78G>A p.A26= | Silent (SNP) | VAF 154/590 reads (26%) | called by muse, mutect2, varscan2
- HAO2 | c.198G>A p.G66= | Silent (SNP) | VAF 132/448 reads (29%) | called by muse, mutect2, varscan2
- HDX | c.1551T>G p.S517= | Silent (SNP) | VAF 124/385 reads (32%) | called by muse, mutect2, varscan2
- HTR1A | c.168C>T p.C56= | Silent (SNP) | VAF 156/582 reads (27%) | catalogued as rs1163044674; called by muse, varscan2
- HTR1E | c.621C>T p.H207= | Silent (SNP) | VAF 242/468 reads (52%) | catalogued as rs377350581; called by muse, mutect2, varscan2
- HUNK | c.966G>A p.E322= | Silent (SNP) | VAF 115/355 reads (32%) | called by muse, mutect2, varscan2
- IFIT1 | c.1335C>T p.F445= | Silent (SNP) | VAF 110/285 reads (39%) | catalogued as rs372737209; called by muse, mutect2, varscan2
- IGF2BP3 | c.561C>T p.S187= | Silent (SNP) | VAF 136/377 reads (36%) | catalogued as rs763385326, COSV51694431; called by muse, varscan2
- IL36A | c.93A>C p.I31= | Silent (SNP) | VAF 82/262 reads (31%) | called by muse, mutect2, varscan2
- INSRR | c.240C>T p.T80= | Silent (SNP) | VAF 208/606 reads (34%) | catalogued as rs149908610; called by muse, mutect2, varscan2
- IP6K1 | c.699C>T p.G233= | Silent (SNP) | VAF 118/378 reads (31%) | catalogued as rs374592396; called by muse, varscan2
- IVL | c.1524G>A p.K508= | Silent (SNP) | VAF 151/474 reads (32%) | called by muse, mutect2, varscan2
- JPH4 | c.1704C>T p.A568= | Silent (SNP) | VAF 186/563 reads (33%) | called by muse, mutect2, varscan2
- KCNV1 | c.492T>G p.T164= | Silent (SNP) | VAF 161/427 reads (38%) | catalogued as COSV52087520; called by muse, mutect2, varscan2
- KIF19 | c.1119C>T p.G373= | Silent (SNP) | VAF 171/537 reads (32%) | catalogued as rs371257733; called by muse, mutect2, varscan2
- KREMEN2 | c.804G>A p.P268= | Silent (SNP) | VAF 210/558 reads (38%) | called by muse, mutect2, varscan2
- LARGE1 | c.381G>A p.G127= | Silent (SNP) | VAF 130/504 reads (26%) | called by muse, mutect2, varscan2
- LCN6 | c.129G>T p.R43= | Silent (SNP) | VAF 18/471 reads (4%) | catalogued as COSV57909846; called by muse, mutect2
- LHX2 | c.813G>A p.T271= | Silent (SNP) | VAF 74/496 reads (15%) | catalogued as rs766869407, COSV65318040; called by muse, mutect2, varscan2
- LMNB2 | c.912C>T p.R304= | Silent (SNP) | VAF 188/534 reads (35%) | catalogued as rs202001996; called by muse, mutect2, varscan2
- LORICRIN | c.501C>T p.G167= | Silent (SNP) | VAF 46/880 reads (5%) | called by muse, mutect2
- LRFN2 | c.586C>T p.L196= | Silent (SNP) | VAF 178/686 reads (26%) | catalogued as COSV57829217; called by muse, mutect2, varscan2
- MCM4 | c.1092G>A p.G364= | Silent (SNP) | VAF 119/603 reads (20%) | called by muse, mutect2, varscan2
- MED13L | c.2874C>T p.S958= | Silent (SNP) | VAF 139/374 reads (37%) | called by muse, mutect2, varscan2
- MFSD6 | c.2169A>G p.L723= | Silent (SNP) | VAF 101/140 reads (72%) | called by muse, mutect2
- MICAL3 | c.4938G>A p.R1646= | Silent (SNP) | VAF 203/747 reads (27%) | catalogued as rs574754671; called by muse, mutect2, varscan2
- MPPED2 | c.135C>T p.D45= | Silent (SNP) | VAF 84/249 reads (34%) | called by muse, mutect2, varscan2
- MROH2B | c.2799A>G p.G933= | Silent (SNP) | VAF 100/424 reads (24%) | called by muse, mutect2, varscan2
- MYO10 | c.4635G>T p.L1545= | Silent (SNP) | VAF 111/483 reads (23%) | called by muse, mutect2, varscan2
- MYO18A | c.300C>T p.A100= | Silent (SNP) | VAF 132/395 reads (33%) | called by muse, mutect2, varscan2
- NFATC4 | c.1623G>A p.T541= | Silent (SNP) | VAF 157/459 reads (34%) | catalogued as rs1222659661, COSV51596200; called by muse, mutect2, varscan2
- NME8 | c.1707T>G p.S569= | Silent (SNP) | VAF 108/301 reads (36%) | called by muse, mutect2, varscan2
- OR5AC2 | c.507T>C p.T169= | Silent (SNP) | VAF 63/213 reads (30%) | catalogued as COSV62279496; called by muse, mutect2, varscan2
- PANK2 | c.1392A>G p.P464= (on ENST00000316562 / NM_153638.3; = p.P173= on NM_024960.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 70/348 reads (20%) | called by muse, mutect2, varscan2
- PAX1 | c.1407G>A p.A469= | Silent (SNP) | VAF 410/741 reads (55%) | catalogued as rs1390951755, COSV68271497; called by muse, mutect2, varscan2
- PCDH17 | c.1875C>T p.Y625= | Silent (SNP) | VAF 322/604 reads (53%) | catalogued as rs1398610173, COSV64976447; called by muse, mutect2, varscan2
- PDCD10 | c.273T>C p.Y91= | Silent (SNP) | VAF 71/271 reads (26%) | called by muse, mutect2, varscan2
- PIGY | c.123C>T p.C41= | Silent (SNP) | VAF 125/378 reads (33%) | called by muse, mutect2, varscan2
- PRDM16 | c.285C>T p.G95= | Silent (SNP) | VAF 22/554 reads (4%) | catalogued as rs1411950795; called by muse, mutect2
- PRKG2 | c.1668C>T p.C556= | Silent (SNP) | VAF 72/265 reads (27%) | catalogued as rs75234128; called by muse, mutect2, varscan2
- PRTN3 | c.213C>T p.H71= | Silent (SNP) | VAF 116/415 reads (28%) | called by muse, mutect2, varscan2
- PSMA3 | c.441G>A p.A147= | Silent (SNP) | VAF 90/256 reads (35%) | catalogued as rs374534971; called by muse, mutect2, varscan2
- PTCH1 | c.3840G>A p.S1280= | Silent (SNP) | VAF 195/499 reads (39%) | catalogued as rs750770371, COSV59472126; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTGS2 | c.126C>T p.C42= | Silent (SNP) | VAF 79/231 reads (34%) | catalogued as rs200215667, COSV66570713; called by muse, mutect2, varscan2
- PTPRB | c.2127C>A p.T709= | Silent (SNP) | VAF 44/310 reads (14%) | catalogued as rs543817374; called by muse, mutect2, varscan2
- PXDNL | c.957C>A p.A319= | Silent (SNP) | VAF 72/517 reads (14%) | called by muse, mutect2, varscan2
- QPRT | c.411G>A p.T137= | Silent (SNP) | VAF 214/589 reads (36%) | catalogued as rs767028115; called by muse, mutect2, varscan2
- RALGDS | c.678C>A p.A226= | Silent (SNP) | VAF 176/526 reads (33%) | called by muse, mutect2, varscan2
- RFX8 | c.753G>A p.T251= (on ENST00000646446; = p.T180= on NM_001145664.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 47/250 reads (19%) | catalogued as rs375431484; called by muse, mutect2, varscan2
- RGS20 | c.1119C>T p.V373= (on ENST00000297313 / NM_170587.4; = p.V226= on NM_003702.4) | Silent (SNP) | VAF 171/414 reads (41%) | called by muse, mutect2, varscan2
- SAFB2 | c.2520C>T p.P840= | Silent (SNP) | VAF 83/265 reads (31%) | catalogued as COSV53042782; called by muse, mutect2
- SAMD12 | c.180T>G p.A60= | Silent (SNP) | VAF 51/459 reads (11%) | called by muse, mutect2, varscan2
- SCART1 | c.1281C>T p.C427= | Silent (SNP) | VAF 103/272 reads (38%) | called by muse, mutect2, varscan2
- SFN | c.342C>A p.A114= | Silent (SNP) | VAF 129/449 reads (29%) | called by muse, mutect2, varscan2
- SLC11A1 | c.1407C>A p.T469= | Silent (SNP) | VAF 255/351 reads (73%) | called by muse, mutect2, varscan2
- SLC25A40 | c.324T>G p.P108= | Silent (SNP) | VAF 42/189 reads (22%) | called by muse, mutect2, varscan2
- SLC35F3 | c.423A>G p.G141= (on ENST00000366617 / NM_001300845.1; = p.G210= on NM_173508.4) | Silent (SNP) | VAF 36/258 reads (14%) | called by muse, mutect2, varscan2
- SLC5A2 | c.1488C>T p.G496= | Silent (SNP) | VAF 156/414 reads (38%) | called by muse, mutect2, varscan2
- SLITRK1 | c.1473C>T p.F491= | Silent (SNP) | VAF 123/523 reads (24%) | called by muse, mutect2, varscan2
- SLITRK2 | c.2499C>T p.L833= | Silent (SNP) | VAF 135/382 reads (35%) | catalogued as COSV59422616; called by muse, mutect2, varscan2
- SLITRK5 | c.2091C>T p.S697= | Silent (SNP) | VAF 137/555 reads (25%) | catalogued as COSV61521683, COSV61522764; called by muse, varscan2
- SNED1 | c.1758A>G p.S586= | Silent (SNP) | VAF 304/390 reads (78%) | called by muse, mutect2, varscan2
- SNED1 | c.3879C>A p.A1293= | Silent (SNP) | VAF 72/609 reads (12%) | called by muse, mutect2, varscan2
- SOX3 | c.1314C>T p.N438= | Silent (SNP) | VAF 150/418 reads (36%) | catalogued as COSV65167852; called by muse, mutect2, varscan2
- SPAG17 | c.1669C>T p.L557= | Silent (SNP) | VAF 95/296 reads (32%) | catalogued as rs1382431704; called by muse, mutect2, varscan2
- SPOCK2 | c.252T>C p.D84= | Silent (SNP) | VAF 13/286 reads (5%) | catalogued as rs1277511923; called by muse, mutect2
- SPRED2 | c.771C>T p.G257= | Silent (SNP) | VAF 172/583 reads (30%) | catalogued as rs1371547169, COSV62691879; called by muse, mutect2, varscan2
- SPTBN2 | c.6804G>A p.V2268= | Silent (SNP) | VAF 146/494 reads (30%) | called by muse, mutect2, varscan2
- STAB1 | c.1306A>C p.R436= | Silent (SNP) | VAF 26/633 reads (4%) | called by muse, mutect2
- SVEP1 | c.10569G>A p.P3523= | Silent (SNP) | VAF 32/304 reads (11%) | catalogued as rs778003240; called by muse, varscan2
- SWT1 | c.1107T>C p.I369= | Silent (SNP) | VAF 62/187 reads (33%) | called by muse, mutect2, varscan2
- SYCE1 | c.477G>A p.E159= (on ENST00000343131 / NM_001143764.3; = p.E123= on NM_130784.3) | Silent (SNP) | VAF 100/278 reads (36%) | called by muse, mutect2, varscan2
- SYNGAP1 | c.1614G>A p.E538= | Silent (SNP) | VAF 126/531 reads (24%) | called by muse, mutect2, varscan2
- TAAR5 | c.108C>T p.V36= | Silent (SNP) | VAF 264/473 reads (56%) | catalogued as rs190791624; called by muse, varscan2
- TBXT | c.1293G>A p.S431= | Silent (SNP) | VAF 127/447 reads (28%) | catalogued as rs140876874; called by muse, mutect2, varscan2
- TET3 | c.2731C>A p.R911= | Silent (SNP) | VAF 354/482 reads (73%) | called by muse, mutect2, varscan2
- TET3 | c.3921G>T p.G1307= | Silent (SNP) | VAF 250/368 reads (68%) | called by muse, varscan2
- TFCP2 | c.873A>G p.S291= | Silent (SNP) | VAF 105/226 reads (46%) | called by muse, mutect2, varscan2
- THSD7A | c.669G>A p.A223= | Silent (SNP) | VAF 15/519 reads (3%) | catalogued as rs974375161, COSV70272498; called by muse, mutect2
- TNPO2 | c.1251G>A p.V417= | Silent (SNP) | VAF 115/355 reads (32%) | catalogued as rs1267207077; called by muse, mutect2, varscan2
- TP73 | c.1464C>T p.H488= | Silent (SNP) | VAF 145/461 reads (31%) | catalogued as rs540572117; called by muse, mutect2, varscan2
- TPO | c.2244G>A p.V748= | Silent (SNP) | VAF 122/383 reads (32%) | called by muse, mutect2, varscan2
- TRPC1 | c.1452T>C p.A484= (on ENST00000476941 / NM_001251845.2; = p.A450= on NM_003304.4) | Silent (SNP) | VAF 32/257 reads (12%) | called by muse, mutect2, varscan2
- TSC22D3 | c.222G>A p.E74= | Silent (SNP) | VAF 18/500 reads (4%) | called by muse, mutect2
- TTLL10 | c.1935G>A p.S645= | Silent (SNP) | VAF 264/697 reads (38%) | catalogued as rs750648601; called by muse, mutect2, varscan2
- UNC13A | c.105C>T p.T35= | Silent (SNP) | VAF 170/390 reads (44%) | catalogued as rs758642064; called by muse, mutect2, varscan2
- USP6NL | c.2328C>T p.G776= | Silent (SNP) | VAF 118/399 reads (30%) | catalogued as rs780264454; called by muse, mutect2, varscan2
- VANGL2 | c.1266G>A p.Q422= | Silent (SNP) | VAF 103/350 reads (29%) | catalogued as COSV63604215; called by muse, mutect2, varscan2
- VCL | c.2802C>A p.A934= | Silent (SNP) | VAF 127/353 reads (36%) | called by muse, mutect2, varscan2
- VPS51 | c.762C>T p.C254= | Silent (SNP) | VAF 205/566 reads (36%) | catalogued as rs767180580; called by muse, mutect2, varscan2
- YTHDC2 | c.924G>A p.S308= | Silent (SNP) | VAF 64/142 reads (45%) | catalogued as rs138017553; called by muse, mutect2, varscan2
- ZNF205 | c.702G>A p.Q234= | Silent (SNP) | VAF 143/467 reads (31%) | called by muse, mutect2, varscan2
- ZNF541 | c.1608G>A p.P536= | Silent (SNP) | VAF 38/524 reads (7%) | catalogued as rs386834267; ClinVar: uncertain significance; called by muse, mutect2
- ZNF568 | c.933A>G p.K311= | Silent (SNP) | VAF 61/184 reads (33%) | catalogued as rs1568411734; called by muse, mutect2, varscan2
- ARMCX4 | c.1039-3488A>G | Intron (SNP) | VAF 141/424 reads (33%) | called by mutect2, varscan2
- DCHS2 | n.4186del | RNA (DEL) | VAF 61/229 reads (27%) | called by mutect2, pindel, varscan2
- DEFB119 | c.61+1254A>G | Intron (SNP) | VAF 106/644 reads (16%) | called by muse, mutect2
- DSG4 | c.2138-63T>A | Intron (SNP) | VAF 120/542 reads (22%) | called by muse, mutect2, varscan2
- FARP1 | c.1414+351T>C | Intron (SNP) | VAF 107/452 reads (24%) | called by muse, mutect2, varscan2
- FBRS | chr16:30659621 C>T | 5'Flank (SNP) | VAF 14/352 reads (4%) | called by muse, mutect2
- KIAA0930 | c.65-13C>T | Intron (SNP) | VAF 27/815 reads (3%) | called by muse, mutect2
- OR5R1 | chr11:56412815 A>T | 3'Flank (SNP) | VAF 107/305 reads (35%) | called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.*654C>T | 3'UTR (SNP) | VAF 79/218 reads (36%) | catalogued as rs956070375; called by muse, mutect2, varscan2
- QRICH2 | c.-112G>A | 5'UTR (SNP) | VAF 73/552 reads (13%) | catalogued as rs1273374784; called by muse, mutect2, varscan2
- SPRR2B | c.*25T>C | 3'UTR (SNP) | VAF 158/453 reads (35%) | catalogued as COSV100482220; called by muse, mutect2, varscan2
- SPTAN1 | c.6693-1148T>C | Intron (SNP) | VAF 37/368 reads (10%) | catalogued as rs1187986772; called by muse, mutect2, varscan2
- TBC1D30 | c.644-2908C>T | Intron (SNP) | VAF 18/526 reads (3%) | called by muse, mutect2
- TJP1 | c.*1141del | 3'UTR (DEL) | VAF 58/167 reads (35%) | catalogued as rs565683119; called by mutect2, varscan2
- ZNF875 | c.-79del | 5'UTR (DEL) | VAF 24/250 reads (10%) | called by mutect2, pindel, varscan2
